Somatic mutation profile of tumor specimen TCGA-BJ-A45K-01A (aliquot TCGA-BJ-A45K-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,138 days).
Specimen TCGA-BJ-A45K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65c6ffad-0960-4bda-b4ee-1fed29f0423d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45K-10A (Blood Derived Normal), aliquot TCGA-BJ-A45K-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77c90a4-072b-42d3-bbd6-6c5a99260f8a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC020765.6 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs546816346, COSV63457250; called by muse, mutect2, varscan2
- RYR1 | c.3575G>T p.S1192I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62095858; called by muse, mutect2, varscan2
- SDK2 | c.4703C>T p.T1568I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs757185853, COSV66185199, COSV66186545; called by muse, mutect2, varscan2
- SPON2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52054875, COSV52055825; called by muse, mutect2, varscan2
- CTSH | c.697dup p.I233Nfs*3 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- DENND6B | c.450G>A p.Q150= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV69806866; called by muse, mutect2, varscan2
- KANSL1 | c.1506G>A p.V502= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV52264995; called by muse, mutect2
